Surgical pathology report (de-identified scan), TCGA case TCGA-QR-A6GS, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site National Institutes of Health, specimen TCGA-QR-A6GS-01A (Primary Tumor).

[page 1 of 2]
Final Results

Surgical Pathology

Final

CASE NUMBER:

DIAGNOSIS: Adrenal, left mass: Pheochromocytoma with capsular invasion; vascular invasion cannot be ruled out; see Note.

NOTE: Sections show a pheochromocytoma. Immunostains are performed and the tumor cells are positive for chromogranin, synaptophysin and S-100. The tumor shows capsular invasion. Vascular invasion cannot be ruled out.

has reviewed the case and concurs.

The immunoperoxidase tests performed here were developed and their performance characteristics determined by the laboratory of Pathology, . They have not been cleared or approved by the U.S. Food and Drug Administration. The FDA has also determined that such clearance or approval is not necessary. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA) as qualified to perform high complexity clinical laboratory testing.

CLINICAL INFORMATION:

Pre-Operative Diagnosis: pheochromocytoma
Post-Operative

pheochromocytoma Operative Findings: large left adrenal

Brief Clinical History: y.o. female with left adrenal

PROCEDURE:

SPECIMENS SUBMITTED: 1. ADRENAL GLAND, LEFT

GROSS DESCRIPTION: Received fresh from the O.R. labeled with the patient's name and medical record number and "left adrenal pheochromocytoma" is a pink/red soft tissue mass measuring 7.5 x 7 x 5 cm and weighing 142.3 gm. The specimen is inked black and bivalved to reveal a red/brown hemorrhagic surface with a central cyst lined by a yellowish fibrous wall measuring 2 cm in largest dimension. A thin partial rim of yellow adrenal cortex is present. Approximately 40% of the tumor mass and a small piece of uninvolved adrenal measuring 0.4 x 0.4 x 0.2 cm is procured for lab. Tissue procured does not involve the inked margins. Gross photographs were taken. The procurement was performed by Dr.

At Surgical Pathology, the specimen received matches the above description. Multiple sections of tumor including capsule and adjacent uninvolved adrenal are sampled and submitted in cassettes

Requested By:

Do not file in Medical Record

[page 2 of 2]
Gross dictated by

No consultants

#

#

Requested By:

Do not file in Medical Record

Criteria	lw 5/22/13	Yes	No
THPAA Discrepancy			
Primary Site Discrepancy			
Qual/Concurrent Primary Noted			
Case is (c) (c)			

Source: NCI Genomic Data Commons file b4b318fe-dd06-4596-9a11-99f145ab7c9f (TCGA-QR-A6GS.35BB9171-E56A-4888-995D-B8D334FB49BD.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).